Somatic mutation profile of tumor specimen ALCH-B0B4-TTP1-A (aliquot ALCH-B0B4-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B0B4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.7 years (21,807 days).
Specimen ALCH-B0B4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc8a3202-35e9-4b48-85bb-0135a995b384.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0B4-NB1-A (Blood Derived Normal), aliquot ALCH-B0B4-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04533ee2-a494-4912-aad8-e8f905692473

The open-access MAF lists 48 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, Intron 4, Nonsense Mutation 2, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 329/747 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 118/494 reads (24%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AVPR2 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs973083544; called by muse, mutect2, varscan2
- CLCN7 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV51970449; called by muse, mutect2, varscan2
- HDAC9 | c.3136G>T p.D1046Y (on ENST00000441542 / NM_178425.3; = p.D1043Y on NM_178423.3) | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV67773067, COSV67779020; called by muse, mutect2
- IGFBP3 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as rs1282395121; called by muse, mutect2, varscan2
- KCNQ3 | c.2485G>C p.E829Q | Missense Mutation (SNP) | VAF 102/434 reads (24%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.778); catalogued as COSV66471185; called by muse, mutect2, varscan2
- MAN1C1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV56045210; called by muse, mutect2
- MUC16 | c.10703C>T p.P3568L | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201851803; called by muse, mutect2, varscan2
- MUC5AC | c.14162G>A p.R4721H | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781484473, COSV100611650; called by muse, mutect2, varscan2
- NLGN4X | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057524668, COSV52033040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NME8 | c.387G>C p.Q129H | Missense Mutation (SNP) | VAF 67/661 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV52247987; called by muse, mutect2, varscan2
- RADX | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV100998800; called by muse, mutect2
- RRP7A | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as rs1479541680; called by muse, mutect2, varscan2
- RUNX1T1 | c.1156C>T p.R386W (on ENST00000265814 / NM_001198628.1; = p.R359W on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/711 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1301792645, COSV56144628; called by muse, mutect2
- SGO2 | c.590C>G p.P197R | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV63413945; called by muse, mutect2
- ASTL | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCAR1 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C8A | c.468C>A p.Y156* | Nonsense Mutation (SNP) | VAF 23/321 reads (7%) | called by muse, mutect2
- CEP295 | c.7451T>G p.I2484R | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- DNAH12 | c.5763C>A p.N1921K (on ENST00000351747; = p.N1940K on NM_001366028.2) | Missense Mutation (SNP) | VAF 90/397 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FILIP1L | c.3082A>C p.K1028Q (on ENST00000354552 / NM_182909.3; = p.K788Q on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/366 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- GFRA1 | c.920T>G p.L307R | Missense Mutation (SNP) | VAF 53/372 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HNRNPUL1 | c.651C>A p.N217K | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2
- MAP2 | c.4136A>G p.D1379G | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MMP9 | c.1055C>G p.T352S | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- NCSTN | c.1755G>T p.Q585H | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NDUFB9 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 37/518 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2
- OR13A1 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PSMC3 | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SHROOM3 | c.5585T>A p.L1862H | Missense Mutation (SNP) | VAF 142/446 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBE2Q2 | c.668A>C p.K223T | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- YAP1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ACTN2 | c.2493C>G p.V831= | Silent (SNP) | VAF 22/551 reads (4%) | catalogued as COSV63973934; called by muse, mutect2
- ADAMTS12 | c.4047G>A p.A1349= | Silent (SNP) | VAF 12/296 reads (4%) | catalogued as rs1390280252, COSV100710419; called by muse, mutect2
- CPPED1 | c.81C>T p.S27= | Silent (SNP) | VAF 26/204 reads (13%) | catalogued as rs566259758, COSV99903263; called by muse, mutect2, varscan2
- DUXA | c.210C>T p.H70= | Silent (SNP) | VAF 20/249 reads (8%) | catalogued as rs368587814; called by muse, mutect2
- GRIK2 | c.396C>A p.T132= | Silent (SNP) | VAF 44/350 reads (13%) | catalogued as rs1053399027; called by muse, mutect2, varscan2
- MRPL39 | c.864C>T p.P288= | Silent (SNP) | VAF 18/193 reads (9%) | called by muse, mutect2, varscan2
- NOX4 | c.1473T>C p.Y491= | Silent (SNP) | VAF 15/181 reads (8%) | called by muse, mutect2, varscan2
- TMEM168 | c.1974C>T p.C658= | Silent (SNP) | VAF 33/419 reads (8%) | catalogued as rs184128444, COSV57182467; called by muse, mutect2
- CARHSP1 | c.-7-2359G>A | Intron (SNP) | VAF 42/158 reads (27%) | catalogued as rs903901498; called by muse, mutect2, varscan2
- HSP90AA4P | n.1149T>C | RNA (SNP) | VAF 10/246 reads (4%) | called by muse, mutect2
- IL2RG | c.455-18A>G | Intron (SNP) | VAF 43/191 reads (23%) | called by muse, mutect2, varscan2
- METTL16 | chr17:2415334 G>A | 3'Flank (SNP) | VAF 12/95 reads (13%) | catalogued as rs1373318830; called by muse, mutect2, varscan2
- RFX3 | c.474+6165C>G | Intron (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- SSPOP | n.11012G>A | RNA (SNP) | VAF 146/191 reads (76%) | called by muse, mutect2, varscan2
- TNRC18 | c.6147+2659G>T | Intron (SNP) | VAF 52/289 reads (18%) | called by muse, mutect2, varscan2
